TARGET case TARGET-40-NAAHDF — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae4873d6-5620-51b2-93c7-3b36bdbaa051

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 8.8 years (3,218 days); Year of diagnosis: 2009; Metastasis at diagnosis: No Metastasis; Days to last follow up: 2,185 days (6.0 years).
   Pathology details: Necrosis percent: 29.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 901 days (2.5 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 901 days (2.5 years); Days to first event: 901 days (2.5 years); First event: Relapse.
- Days to follow up: 2,185 days (6.0 years); Year of follow up: 2015.

Biospecimens (3 samples)
- Sample TARGET-40-NAAHDF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHDF-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHDF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2185
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Other bone
- Histologic response: Stage 1/2 (0-90 % necrosis)
